CCDI case PBBJKE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a4db6549-51ae-46b0-a226-1124e1900ad2

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9473/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.3 years (4,863 days).

Biospecimens (3 samples)
- Sample 0DAWAG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DAWAH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DAWAQ: Tissue type: Tumor; Specimen type: Solid Tissue.
